Gene-level copy-number profile of tumor specimen TCGA-AL-A5DJ-01A from TCGA case TCGA-AL-A5DJ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 55.0 years (20,079 days).
Specimen TCGA-AL-A5DJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.ad1ff4b7-be72-447b-91d3-c6b8fad7ba14.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AL-A5DJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d9640498-ef01-419e-acf9-59bb5995f6fa

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 110; copy number 1: 4; copy number 2: 2,156; copy number 3: 1,606; copy number 4: 12,843; copy number 5: 4,356; copy number 6: 23,184; copy number 7: 6,222; copy number 8: 8,729; copy number 9: 338; copy number 10: 271.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AL-A5DJ-01): tumor purity 0.66, ploidy 2.89, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 110 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:48,701,491–48,795,513, 2 genes: FO393412.1, AL391538.1.
- chr9:20,999,509–27,844,481, 105 genes (broad region; genes not listed).
- chr10:56,357,227–56,596,031, 3 genes: ZWINT, AC010996.1, AC025039.1.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
